Surgical pathology report (de-identified scan), TCGA case TCGA-77-7139, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7139-01A (Primary Tumor).

[page 1 of 2]
HISTORY

RLL Ca. PET scan positive hilar LN.

MACROSCOPIC

Nine specimens received.

1: The specimen is labelled "R upper lobe" and consists of an upper lobe measuring 190 x 85 x 45 mm. Just superior and lateral to the main bronchus is a tumour which, on the external surface, measures approximately 38 mm in diameter. On sectioning the tumour measures 28 mm. Distal to this there is bronchiectasis and some endogenous lipid pneumonia. Adjacent to the mass there appears to be an adherent involved lymph node. Sectioning of the lung tissue away from the tumour reveals no other lesions. A tongue of tumour protrudes into the main bronchus but invasive tumour appears to be clear by at least 5 mm. [Bronchus and peribronchial lymph nodes, A; tumour, B-C; adherent apparently involved lymph node, D; tongue of tumour and adjacent bronchus, E; lung tissue distal to the tumour, F; random section of lung, G].

2: The specimen is labelled "right middle lobe lymph node" and consists of a fragment of grey-black tissue measuring 23 x 23 x 5 mm. [[Wrapped and blocked in toto, 2A].

3: The specimen is labelled "right upper lobe lymph node" and consists of two pieces of lymph node tissue, one of which measures 25 x 12 x 8 mm, and the other measures 7 mm in maximal dimension. [The largest piece bisected and all wrapped and BIT, 3A].

4: The specimen is labelled "No. 7 lymph node" and consists of three pieces of lymph node tissue measuring 35 x 25 x 6 mm in aggregate. [BIT, 4A].

5: The specimen is labelled "No. 8 lymph node" and consists of pieces of lymph node measuring 32 x 20 x 5 mm. [Wrapped and blocked in toto, 5A].

6: The specimen is labelled "No. 9 lymph node" and consists of a piece of lymph node measuring 13 x 6 x 3 mm. [BIT, 6A].

7: The specimen is labelled "azygous" and consists of a piece of blackened lymph node measuring 13 x 8 x 7 mm. [BIT as 3TS, 7A].

8: The specimen is labelled "right main bronchus" and consists of a piece of lymph node measuring 18 x 13 x 10 mm. There is no apparent adherent bronchus. On sectioning the node has a sclerotic appearance and has white and yellow flecks. [BIT as 3TS, 8A].

9: The specimen is labelled "right bronchial stump" and consists of a segment of bronchus with a transverse line of staples measuring 23 x 10 x 5 mm. [Blocked as 2TS away from the staple line, 9A].

MICROSCOPY

1: Sections show a poorly differentiated squamous cell carcinoma. There is prominent endobronchial component. In situ squamous cell carcinoma extends to the bronchial resection margin but the margin appears clear of invasive tumour. In one area, the overlying pleura appears thickened and scarred. There are features suspicious for pleural invasion within this area and special stains will be performed to assess this. The tumour is not present on the pleural surface. No blood vessel, lymphatic or perineural invasion is seen. The tumour appears to directly invade a peribronchial lymph node. The adjacent lung shows no significant changes.

2: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

3: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

4: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

5: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

[page 2 of 2]
6: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

7: Sections of the lymph nodes show reactive changes and a small silicotic nodule. There is no evidence of malignancy.

8: Sections show squamous cell carcinoma, which is surrounded by a dense fibrous capsule. Some lymphoid aggregates present in this region and it is presumed that this deposit of squamous cell carcinoma is present within a lymph node. An adjacent smaller lymph node is present and this shows reactive changes only. No bronchial wall is present for assessment. Tumour extends extremely closely to the diathermied resection margin.

9: Sections of the bronchus show a small amount of residual squamous cell carcinoma in situ. No invasive carcinoma is seen.

SUMMARY

Right upper lobe and hilar and mediastinal lymph nodes:

- 1: Poorly differentiated squamous cell carcinoma; 28 mm in maximal dimension.
- 2: No blood vessel, lymphatic or perineural invasion present.
- 3: Probable pleural invasion identified; special stains being performed.
- 4: Squamous cell carcinoma in situ extends to bronchial margin but invasive component clear.
- 5: No lymph node metastases.
- 6: T2N1MX

T-28000 M-80703 P1-03000

Source: NCI Genomic Data Commons file eaaf7971-e6cc-4acb-9194-8522e2b516db (TCGA-77-7139.6E64F460-AB1C-478E-9B44-288CA9D5875F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).